Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4340, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4340-01A (Primary Tumor).

[page 1 of 2]
Right renal cortical tumor. Laparoscopic right nephrectomy.

1: SP: Right kidney (sr)

1) KIDNEY, RIGHT; LAPAROSCOPIC NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE II/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 4.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR
- THE NON-NEOPLASTIC KIDNEY SHOWS GLOMERULOSCLEROSIS AND INTERSTITIAL INFLAMMATION.
- THE ADRENAL GLAND IS NOT SUBMITTED.

Result

Comment

1) The specimen is received fresh, labeled "Right Kidney". It consists of a kidney with focally attached perirenal fat, superiorly, inferiorly and posteriorly measuring 440 grams, 20 x 8.6 x 4.5 cm altogether. The kidney measures 12 x 8 x 4 cm with attached ureter measuring 6 x 0.3 cm. The anterior renal capsule is exposed. The posterior renal capsule is also focally exposed. The margin is inked. The ureter and the vascular margins are taken. The specimen is bivalved revealing a subcapsular, well-circumscribed, yellow-brown mass with a central scar measuring 4.5 x 4.5 x 4.0 cm. The tumor is limited to the renal cortex and abuts the renal capsule, but does not penetrate it. The renal calyces and pelvis are uninvolved. The renal vein, artery and ureter are also uninvolved. Representative sections are submitted. A portion of the specimen is given to TPS. A photograph is taken.

UM – ureteral margin

TAM – tumor with ant

CHEN, Y. and F. CHEN, 1997. The

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

TP – tumor with renal pelvis
N – normal parenchyma
HF – hilar fat, for possible lymph nodes

Summary of Sections:

Part 1: SP: Right kidney (sr)

Block	Sect. Site	PCs
1	HF	2
1	N	1
2	TAM	2
1	TP	1
2	TPM	2
1	UM	1
1	VM	2

Source: NCI Genomic Data Commons file 1ac0e97b-8c98-48fa-900c-df6763ed4d3b (TCGA-BP-4340.9DFD0764-2BF4-46F1-8BFB-5C89BFEAB3B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).